Gene-level copy-number profile of tumor specimen TCGA-06-A7TL-01A from TCGA case TCGA-06-A7TL, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 30.9 years (11,297 days).
Specimen TCGA-06-A7TL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.a8684221-6b51-4221-a122-2ebcc553bbe3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-A7TL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9b8d9a6b-f76d-476d-af84-58ccf885d12b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 5; copy number 2: 6,961; copy number 3: 2,899; copy number 4: 44,044; copy number 5: 4,089; copy number 6: 281; copy number 7: 516; copy number 8: 3; copy number 14: 864; copy number 18: 18; copy number 26: 19; copy number 27: 8; copy number 28: 25; copy number 29: 10; copy number 30: 51; copy number 31: 11; copy number 33: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-A7TL-01A-11D-A390-01): tumor purity 0.79, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,016 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:857,124–1,730,474, 7 genes, copy number 33: AC090044.1, AC087430.1, RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39.
- chr3:2,088,933–2,089,211, 1 gene, copy number 33: RN7SKP144.
- chr3:2,110,409–2,144,241, 2 genes, copy number 33: CNTN4-AS2, AC087427.1.
- chr3:4,269,153–4,985,323, 10 genes, copy number 29: AC023483.1, SETMAR, MRPS10P2, ITPR1-DT, ITPR1, EGOT, AC018816.2, AC018816.1, BHLHE40-AS1, BHLHE40.
- chr3:6,490,460–6,805,479, 3 genes, copy number 31: AC069277.1, GRM7-AS3, AC069277.2.
- chr3:6,773,037–6,894,022, 2 genes, copy number 31: MRPS36P1, GRM7-AS2.
- chr3:9,292,588–10,321,112, 50 genes, copy number 30: AC026191.1, PGAM1P4, THUMPD3-AS1, THUMPD3, SETD5, LHFPL4, DUSP5P2, MTMR14, AC022382.2, CPNE9, BRPF1, OGG1, CAMK1, TADA3, ARPC4, ARPC4-TTLL3, TTLL3, AC022382.1, RPUSD3, CIDEC, JAGN1, IL17RE, IL17RC, RNU6-882P, AC018809.3, CRELD1, AC018809.1, PRRT3, PRRT3-AS1, AC018809.2, EMC3, EMC3-AS1, CYCSP10, AC022007.1, CIDECP1, FANCD2, RNU6-670P, CYCSP11, FANCD2OS, BRK1, VHL, AC034193.1, IRAK2, TATDN2, AC022384.1, LINC00852, GHRL, GHRLOS, AC022384.2, SEC13.
- chr3:10,330,229–10,330,285, 1 gene, copy number 30: MIR378B.
- chr3:12,484,432–12,885,211, 16 genes, copy number 26 (within-gene range 4–26): TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17, CAND2, AC034198.2, RPL32, SNORA7A, AC034198.1, LINC02022.
- chr3:14,348,451–14,489,349, 3 genes, copy number 26: LINC01267, RNA5SP124, SLC6A6.
- chr3:16,524,771–17,090,604, 8 genes, copy number 27: LINC00690, AC010139.1, DAZL, AC091493.1, CDYLP1, PLCL2, MIR3714, PLCL2-AS1.
- chr3:24,430,748–24,681,711, 6 genes, copy number 31: RPL31P20, THRB-IT1, THRB-AS1, AC012087.2, AC012087.1, EIF3KP2.
- chr3:31,161,704–32,508,325, 25 genes, copy number 28: MIR466, CNN2P6, RNA5SP127, H3P11, THRAP3P1, STT3B, OSBPL10, OSBPL10-AS1, ZNF587P1, ZNF860, RPL21P40, AC094019.1, Y_RNA, NIFKP7, GPD1L, AC094019.2, RPSAP11, AC097639.1, CMTM8, AC097639.2, KRT18P15, CMTM7, CMTM6, MIR548AY, AC104306.1.
- chr12:66,767–40,211,419, 882 genes, copy number 14–18 (within-gene range 2–18) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
